Gene-level copy-number profile of tumor specimen TCGA-86-6562-01A from TCGA case TCGA-86-6562, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.8 years (19,301 days).
Specimen TCGA-86-6562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5e8c8cf1-7c6c-482c-9422-862ff01a31ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-6562-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a159c4c-8a11-421f-8761-ed7894fd8679

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 14,794; copy number 3: 25,309; copy number 4: 11,485; copy number 5: 1,105; copy number 6: 4,233; copy number 7: 2,604; copy number 8: 119; copy number 9: 87; copy number 10: 38; copy number 12: 3; copy number 13: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-6562-01A-11D-1752-01): tumor purity 0.46, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,894 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,206,427–248,919,946, 2,773 genes, copy number 7–12 (broad region; genes not listed).
- chr20:7,146,467–8,999,100, 18 genes, copy number 8 (within-gene range 2–8): LINC01428, AL080248.1, LINC01751, LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP.
- chr20:10,672,695–10,994,924, 1 gene, copy number 8 (within-gene range 5–8): AL050403.2.
- chr20:10,753,278–11,029,455, 5 genes, copy number 8: AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1.
- chr20:12,865,202–13,008,417, 4 genes, copy number 9: LINC01722, AL078623.1, AL133331.1, LINC01723.
- chr20:21,947,647–24,680,991, 69 genes, copy number 8–13 (broad region; genes not listed).
- chr20:25,624,045–26,251,546, 24 genes, copy number 9 (within-gene range 5–9): ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
